Somatic mutation profile of tumor specimen TCGA-05-4397-01A (aliquot TCGA-05-4397-01A-01D-1265-08) from TCGA case TCGA-05-4397, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.3 years (23,833 days).
Specimen TCGA-05-4397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8b0380b-818a-4689-a1dc-5bbecc611b7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4397-10A (Blood Derived Normal), aliquot TCGA-05-4397-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5705599-51bd-4f67-83ba-a1e1a1bdd62f

The open-access MAF lists 909 somatic variants for this specimen: 706 protein-altering or splice-affecting, 178 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 604, Silent 178, Nonsense Mutation 50, Frame Shift Del 25, Splice Site 14, Intron 14, RNA 8, Frame Shift Ins 5, Splice Region 3, Translation Start Site 3, 3'UTR 2, In Frame Del 2.

Variants (750 of 909; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA9 | c.4623G>T p.Q1541H | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs188409024, COSV60627103, COSV60629650; called by muse, mutect2, varscan2
- ABCC12 | c.3741G>T p.Q1247H | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs1567442631, COSV60915024; called by muse, mutect2, varscan2
- ABCC8 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs751209734, COSV56848032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABT1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs782192030, COSV51291783; called by muse, mutect2, varscan2
- ACAP3 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100686119; called by muse, mutect2, varscan2
- ACE | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52008923; called by muse, mutect2, varscan2
- ACER3 | c.449G>C p.G150A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.411); catalogued as rs1555019152, COSV53600701; called by muse, mutect2, varscan2
- ACOX3 | c.1468G>T p.D490Y | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs759487661, COSV62712578; called by muse, mutect2, varscan2
- ADAM8 | c.641del p.Q214Rfs*17 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as COSV69864275; called by mutect2, pindel, varscan2
- ADAMTS16 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56995220; called by muse, varscan2
- ADAMTS2 | c.2812C>A p.R938S | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368069, COSV52381148; called by muse, mutect2, varscan2
- ADAMTS9 | c.2158G>C p.V720L | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55784375; called by muse, mutect2, varscan2
- ADCY10 | c.4519C>A p.P1507T | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV63242028; called by muse, mutect2, varscan2
- ADCY2 | c.1776C>A p.Y592* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV57858993; called by muse, mutect2, varscan2
- ADCY5 | c.2206C>T p.H736Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV59199997; called by muse, mutect2, varscan2
- ADCY9 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53572456; called by muse, mutect2, varscan2
- ADGRA1 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 7/8 reads (88%) | catalogued as COSV74142859; called by muse, varscan2
- ADGRE1 | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV51673784, COSV51677393; called by muse, varscan2
- ADGRE1 | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV51677403; called by muse, varscan2
- ADGRG3 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59651594; called by muse, mutect2, varscan2
- ADGRG4 | c.6822+1G>T p.X2274_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as COSV54960334; called by muse, varscan2
- ADGRL2 | c.4300A>T p.I1434L (on ENST00000370717 / NM_001366005.1; = p.I1378L on NM_012302.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV54674404; called by muse, mutect2, varscan2
- ADGRL3 | c.1667C>G p.S556W (on ENST00000506720 / NM_001322402.2; = p.S488W on NM_015236.6) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV72231044; called by muse, mutect2, varscan2
- ADGRV1 | c.16222del p.W5408Gfs*17 | Frame Shift Del (DEL) | VAF 37/100 reads (37%) | catalogued as COSV101316350; called by mutect2, pindel, varscan2
- AGAP1 | c.1895C>T p.P632L (on ENST00000304032 / NM_001037131.3; = p.P579L on NM_014914.5) | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58330897; called by muse, mutect2, varscan2
- AGMO | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61115713; called by muse, mutect2, varscan2
- AGPAT3 | c.877A>G p.M293V | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52371554; called by muse, mutect2, varscan2
- AGPS | c.1612G>T p.V538L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51565843; called by muse, mutect2, varscan2
- AGTR1 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV62558762; called by muse, mutect2
- AL592490.1 | c.1231A>T p.T411S | Missense Mutation (SNP) | VAF 97/130 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs772877174, COSV101308324, COSV69426798; called by muse, mutect2, varscan2
- ALDH1B1 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV66620145; called by mutect2, varscan2
- ALDH9A1 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1343526557, COSV61340239; called by muse, mutect2
- ALG13 | c.2935A>T p.T979S | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV52642587, COSV99321802; called by muse, mutect2, varscan2
- ALK | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV66574945; called by muse, mutect2
- ALPK2 | c.2393G>C p.R798T | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs773730533, COSV64494216; called by muse, mutect2, varscan2
- AMMECR1L | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55760371, COSV99761271; called by muse, mutect2, varscan2
- AMPH | c.1996G>T p.V666L | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as rs776256855, COSV57747149; called by muse, mutect2, varscan2
- ANGPT2 | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as COSV57337964, COSV57339537; called by muse, mutect2, varscan2
- ANGPT4 | c.1446C>A p.H482Q | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV67922065; called by muse, mutect2, varscan2
- ANGPT4 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67922069, COSV67922571; called by muse, mutect2, varscan2
- ANK1 | c.3590C>G p.A1197G | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV55885673; called by muse, mutect2, varscan2
- ANK3 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55051020, COSV55065453; called by muse, mutect2, varscan2
- ANKRA2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.957); catalogued as COSV99706958; called by muse, mutect2, varscan2
- ANKRD1 | c.840C>G p.I280M | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV65467132, COSV65467888; called by mutect2, varscan2
- ANKRD17 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV58223091; called by muse, varscan2
- ANO3 | c.47-2A>C p.X16_splice | Splice Site (SNP) | VAF 66/159 reads (42%) | catalogued as COSV56797122; called by muse, mutect2, varscan2
- ANPEP | c.2752-1G>C p.X918_splice | Splice Site (SNP) | VAF 72/185 reads (39%) | catalogued as COSV100262752, COSV100263485; called by muse, mutect2, varscan2
- AP5M1 | c.36A>T p.E12D | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99841089; called by muse, mutect2, varscan2
- APC | c.3934G>C p.G1312R | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV57321523, COSV57355837; called by muse, mutect2, varscan2
- ARHGAP20 | c.1543C>G p.P515A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV52814118; called by muse, mutect2, varscan2
- ARHGAP25 | c.110C>A p.P37Q (on ENST00000409202 / NM_001007231.3; = p.P30Q on NM_014882.3) | Missense Mutation (SNP) | VAF 178/463 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54904362; called by muse, mutect2, varscan2
- ARHGAP31 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51795340; called by muse, mutect2, varscan2
- ARHGAP5 | c.2927A>G p.N976S | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.066); catalogued as COSV61537007; called by muse, mutect2, varscan2
- ARHGEF12 | c.742C>A p.Q248K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV63105822, COSV63106844; called by muse, mutect2, varscan2
- ARHGEF38 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs147662568; called by muse, mutect2, varscan2
- ARID2 | c.482T>A p.L161* | Nonsense Mutation (SNP) | VAF 50/106 reads (47%) | catalogued as COSV57608048; called by muse, mutect2, varscan2
- ARID4A | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV62162316; called by muse, mutect2, varscan2
- ART4 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV57452452; called by muse, mutect2, varscan2
- ASPM | c.5236A>C p.K1746Q | Missense Mutation (SNP) | VAF 137/224 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV54132760; called by muse, mutect2, varscan2
- ASTN2 | c.1855G>T p.D619Y (on ENST00000313400 / NM_001365069.1; = p.D568Y on NM_014010.5) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1268297670, COSV57761093, COSV57791154; called by muse, mutect2, varscan2
- ASXL3 | c.5461A>T p.R1821* | Nonsense Mutation (SNP) | VAF 100/254 reads (39%) | catalogued as COSV52470740; called by muse, mutect2, varscan2
- ATAD2 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV54882910; called by muse, mutect2
- ATP10B | c.3190C>A p.Q1064K | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59156742; called by muse, varscan2
- ATP10B | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV58779427; called by muse, mutect2, varscan2
- ATP11B | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60030158; called by muse, mutect2, varscan2
- ATP2C1 | c.1540A>C p.K514Q | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV60758442; called by muse, mutect2, varscan2
- ATRN | c.2192A>G p.N731S | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV53529794; called by muse, mutect2
- AVPR1B | c.652T>C p.C218R | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1487097112, COSV100899332; called by muse, mutect2, varscan2
- AZU1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as rs1051889574, COSV52141505; called by muse, mutect2, varscan2
- BAIAP3 | c.1767A>G p.P589= | Splice Region (SNP) | VAF 166/413 reads (40%) | catalogued as COSV50104326; called by muse, mutect2, varscan2
- BBOX1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs147348000; called by muse, mutect2
- BBX | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57887944; called by muse, mutect2, varscan2
- BCL9L | c.1581C>G p.Y527* | Nonsense Mutation (SNP) | VAF 51/140 reads (36%) | catalogued as COSV99418844; called by muse, mutect2, varscan2
- BEND3 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV100944565; called by muse, mutect2, varscan2
- BFSP2 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV56589866; called by muse, mutect2, varscan2
- BICD1 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55682038; called by muse, mutect2, varscan2
- BIRC3 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV54817706; called by muse, mutect2, varscan2
- BOD1L1 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV50021623; called by muse, mutect2, varscan2
- BRCA2 | c.6187G>A p.G2063R | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66456623; called by muse, mutect2, varscan2
- BRD4 | c.3576+1G>T p.X1192_splice | Splice Site (SNP) | VAF 48/141 reads (34%) | catalogued as COSV99650094; called by muse, mutect2, varscan2
- BRD4 | c.3576G>T p.K1192N | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99650096; called by muse, mutect2, varscan2
- BRDT | c.2143T>A p.S715T | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100746122, COSV62865666; called by muse, mutect2, varscan2
- BRINP1 | c.2263C>A p.Q755K | Missense Mutation (SNP) | VAF 112/267 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56304513; called by muse, mutect2, varscan2
- BRINP2 | c.1684G>T p.G562W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV64178429; called by muse, mutect2, varscan2
- BRINP3 | c.2240A>C p.Q747P | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV66529453; called by muse, mutect2, varscan2
- BRSK2 | c.1213del p.Q405Sfs*26 | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | catalogued as COSV57548067; called by mutect2, pindel, varscan2
- C14orf39 | c.1594G>T p.G532C | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV58783072; called by muse, mutect2
- C19orf47 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100775033; called by muse, mutect2, varscan2
- C1orf127 | c.1380G>T p.Q460H | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.989); catalogued as COSV65439506; called by muse, mutect2, varscan2
- C2orf42 | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV52451112; called by muse, mutect2, varscan2
- C5orf22 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57599023; called by muse, mutect2, varscan2
- C7orf31 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52218589; called by muse, mutect2, varscan2
- CA5A | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 152/376 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV59241632; called by muse, mutect2, varscan2
- CABS1 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56733950; called by muse, mutect2, varscan2
- CABYR | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV100509960; called by muse, mutect2, varscan2
- CACNA1E | c.5159C>A p.A1720D | Missense Mutation (SNP) | VAF 148/543 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62402463; called by muse, mutect2, varscan2
- CAMSAP1 | c.3214C>T p.P1072S | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56724287; called by muse, mutect2, varscan2
- CAPN9 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV55235782; called by muse, mutect2, varscan2
- CBR4 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60370359; called by muse, mutect2, varscan2
- CCDC141 | c.2540T>C p.L847S | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV99836366; called by muse, mutect2, varscan2
- CCDC197 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0.022); catalogued as COSV100113611; called by muse, mutect2, varscan2
- CCDC197 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.837); catalogued as COSV100113613; called by muse, mutect2, varscan2
- CCNT2 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV99750273; called by muse, mutect2, varscan2
- CD163 | c.2839G>T p.G947* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV63134362; called by muse, mutect2, varscan2
- CD46 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV100522809; called by mutect2, varscan2
- CD5L | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 35/55 reads (64%) | catalogued as COSV63822389; called by muse, mutect2, varscan2
- CD86 | c.943A>G p.K315E (on ENST00000330540 / NM_175862.5; = p.K309E on NM_006889.4) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52607957; called by muse, mutect2, varscan2
- CDC16 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 112/214 reads (52%) | catalogued as COSV52960353; called by muse, mutect2, varscan2
- CDH2 | c.2522A>T p.K841I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52285355; called by muse, mutect2, varscan2
- CDH22 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.92); PolyPhen benign (0.087); catalogued as COSV64838297; called by muse, mutect2, varscan2
- CDH9 | c.1849G>C p.V617L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV50282071, COSV50318030; called by muse, mutect2, varscan2
- CDK12 | c.2535A>C p.E845D | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV71001410; called by muse, mutect2, varscan2
- CDYL | c.803C>T p.P268L (on ENST00000328908 / NM_001368125.1; = p.P214L on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV59360395; called by muse, mutect2, varscan2
- CELSR1 | c.6370A>G p.T2124A | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV53093386; called by muse, mutect2, varscan2
- CENPF | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV65276151; called by muse, mutect2, varscan2
- CENPF | c.3733C>T p.L1245F | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV65276156; called by muse, mutect2, varscan2
- CENPF | c.5362C>T p.H1788Y | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV65276159; called by muse, mutect2, varscan2
- CENPF | c.5861C>T p.S1954L | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as rs1257572014, COSV65276163; called by muse, mutect2
- CENPF | c.6062C>G p.S2021C | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as rs762653487, COSV100871679, COSV65276166; called by muse, varscan2
- CENPF | c.6745C>A p.Q2249K | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1447476935, COSV65276168; called by muse, mutect2, varscan2
- CENPF | c.8080G>C p.E2694Q | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV65276173; called by muse, mutect2, varscan2
- CENPF | c.8233G>A p.E2745K | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs747975726, COSV65276179; called by muse, mutect2, varscan2
- CENPF | c.8566G>A p.E2856K | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65276186; called by muse, varscan2
- CENPF | c.8752G>A p.E2918K | Missense Mutation (SNP) | VAF 60/274 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV65276190; called by muse, varscan2
- CFH | c.3311-1G>T p.X1104_splice | Splice Site (SNP) | VAF 73/258 reads (28%) | catalogued as COSV100810173, COSV66406587; called by muse, mutect2, varscan2
- CFHR4 | c.1192C>A p.P398T (on ENST00000367416 / NM_001201551.2; = p.P152T on NM_006684.5) | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52231068; called by muse, mutect2, varscan2
- CHAT | c.1485A>T p.L495F | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV60327623; called by muse, mutect2, varscan2
- CHD1L | c.2122G>T p.D708Y | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV63615115; called by muse, mutect2, varscan2
- CHD2 | c.1421C>G p.P474R | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59121002; called by muse, mutect2, varscan2
- CHRNA6 | c.116A>G p.H39R | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99373099; called by muse, mutect2, varscan2
- CHST1 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.318); catalogued as COSV57324288; called by muse, mutect2, varscan2
- CHST15 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as COSV60563356, COSV60565068; called by muse, mutect2, varscan2
- CIB4 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.068); catalogued as COSV56601848; called by muse, mutect2, varscan2
- CLASP2 | c.2616G>T p.Q872H | Missense Mutation (SNP) | VAF 109/160 reads (68%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.888); catalogued as COSV56285932; called by muse, mutect2, varscan2
- CLDN17 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54523491; called by muse, mutect2, varscan2
- CLEC6A | c.464C>A p.T155K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV65987616; called by muse, mutect2, varscan2
- CLMN | c.2686A>T p.S896C | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV54183885; called by muse, mutect2, varscan2
- CMKLR1 | c.1048C>A p.H350N (on ENST00000312143 / NM_001142344.2; = p.H348N on NM_004072.3) | Missense Mutation (SNP) | VAF 75/136 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV56439419; called by muse, mutect2, varscan2
- CMKLR1 | c.410G>T p.R137L (on ENST00000312143 / NM_001142344.2; = p.R135L on NM_004072.3) | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56439427; called by muse, mutect2, varscan2
- CNBD1 | c.797C>G p.T266S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV73073921; called by muse, mutect2, varscan2
- CNTNAP4 | c.2501T>A p.L834* | Nonsense Mutation (SNP) | VAF 83/183 reads (45%) | catalogued as COSV56687919; called by muse, mutect2, varscan2
- COL22A1 | c.3868del p.R1290Gfs*138 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | catalogued as rs777178588, COSV57339482; called by mutect2, pindel, varscan2
- COL2A1 | c.430-1G>T p.X144_splice | Splice Site (SNP) | VAF 87/188 reads (46%) | catalogued as CS104511, COSV61531888; called by muse, mutect2, varscan2
- COL3A1 | c.3497G>A p.R1166Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369494336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.4528G>T p.V1510L | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65427793; called by muse, mutect2, varscan2
- COL4A4 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV61633659; called by muse, mutect2, varscan2
- COL5A2 | c.1699G>T p.G567W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66411167; called by muse, mutect2, varscan2
- COL6A3 | c.4004G>T p.G1335V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55095514; called by muse, mutect2, varscan2
- COL9A1 | c.2726A>C p.Q909P | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV57886747; called by muse, mutect2, varscan2
- CRB1 | c.1281C>G p.N427K | Missense Mutation (SNP) | VAF 118/208 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.218); catalogued as COSV66330396, COSV66331355; called by muse, mutect2, varscan2
- CRB2 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs370059953, COSV63505917; called by muse, mutect2, varscan2
- CRH | c.539T>A p.L180* | Nonsense Mutation (SNP) | VAF 47/118 reads (40%) | catalogued as COSV99396165; called by muse, mutect2, varscan2
- CRIPT | c.132dup p.A45Sfs*4 | Frame Shift Ins (INS) | VAF 18/44 reads (41%) | catalogued as rs771238795; called by mutect2, varscan2
- CRYGC | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV52205610; called by muse, mutect2, varscan2
- CSMD2 | c.4528C>A p.P1510T | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53926998; called by muse, mutect2, varscan2
- CSMD3 | c.2995C>A p.H999N (on ENST00000297405 / NM_001363185.1; = p.H895N on NM_052900.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.729); catalogued as COSV52225343; called by muse, mutect2, varscan2
- CTAGE15 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV69482068; called by muse, mutect2, varscan2
- CTNND1 | c.1174C>T p.H392Y | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62384467; called by muse, mutect2, varscan2
- CTSD | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs200303993, COSV52588586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCL12 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 27/172 reads (16%) | catalogued as COSV59108108; called by muse, varscan2
- CYLC2 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV104425771, COSV66338167; called by muse, mutect2, varscan2
- CYP7A1 | c.593A>G p.Q198R | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.62); catalogued as COSV56964318; called by muse, mutect2, varscan2
- DBT | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64495759; called by muse, mutect2, varscan2
- DDRGK1 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as COSV100621393; called by muse, mutect2, varscan2
- DDRGK1 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1250018974, COSV100621394; called by muse, mutect2, varscan2
- DDX18 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99604404; called by muse, mutect2, varscan2
- DDX4 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61755764; called by muse, mutect2, varscan2
- DEFA4 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV52405045; called by muse, mutect2, varscan2
- DELE1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV52005446; called by muse, mutect2, varscan2
- DENND2A | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755191369, COSV52053692; called by muse, mutect2, varscan2
- DGKB | c.2292G>C p.M764I | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV51795885; called by muse, mutect2, varscan2
- DIDO1 | c.5324G>C p.R1775T | Missense Mutation (SNP) | VAF 145/296 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV56626665; called by muse, mutect2, varscan2
- DISP2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV51127236; called by muse, mutect2, varscan2
- DISP3 | c.1813G>T p.V605L | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53830506, COSV99610200; called by muse, mutect2, varscan2
- DLGAP4 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100211424, COSV59419705; called by muse, mutect2, varscan2
- DLK1 | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57992329; called by muse, mutect2, varscan2
- DLL1 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV64537330, COSV64537862; called by muse, mutect2, varscan2
- DLST | c.672+1del | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | catalogued as COSV53166638; called by mutect2, pindel, varscan2
- DMD | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 52/53 reads (98%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV55881959; called by muse, mutect2, varscan2
- DNAH11 | c.7824G>T p.Q2608H | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as COSV60963839; called by muse, mutect2, varscan2
- DNAH17 | c.3637G>C p.E1213Q | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.292); catalogued as COSV101101687; called by muse, mutect2, varscan2
- DNAH5 | c.11147T>G p.F3716C | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54217889, COSV54235391; called by muse, mutect2, varscan2
- DNAH8 | c.8279T>C p.I2760T | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV59458865; called by muse, mutect2, varscan2
- DNAJA2 | c.1003G>T p.V335L | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV57695036; called by muse, mutect2, varscan2
- DNM1 | c.1877A>T p.Y626F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV57852990; called by muse, mutect2, varscan2
- DOCK5 | c.3122A>T p.Q1041L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52405090; called by muse, mutect2, varscan2
- DPP10 | c.1154T>C p.F385S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59696991; called by muse, mutect2, varscan2
- DTNA | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV52010765; called by muse, mutect2, varscan2
- DUOX1 | c.4231C>G p.Q1411E | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV52051330; called by muse, mutect2, varscan2
- EDEM3 | c.1126T>G p.Y376D | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV58925533; called by muse, mutect2, varscan2
- EDNRB | c.299G>T p.R100L (on ENST00000377211 / NM_001201397.1; = p.R10L on NM_000115.5) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV57519857, COSV57524856; called by muse, mutect2, varscan2
- EFL1 | c.3311A>T p.E1104V | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV51607061; called by muse, mutect2, varscan2
- EFTUD2 | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68183592; called by muse, mutect2, varscan2
- EMILIN1 | c.2015G>A p.G672D | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.32); catalogued as COSV53155490; called by muse, mutect2, varscan2
- EML5 | c.4556C>A p.A1519E (on ENST00000380664; = p.A1527E on NM_183387.3) | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV61347689; called by muse, mutect2, varscan2
- ENTHD1 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 114/269 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.457); catalogued as COSV57321911; called by muse, mutect2, varscan2
- EPHA2 | c.1329G>T p.R443S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV64453719; called by muse, mutect2, varscan2
- EPHA5 | c.1136C>A p.P379Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV104384938, COSV56658591; called by muse, mutect2, varscan2
- EPM2AIP1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV51620174; called by muse, mutect2, varscan2
- ERCC6 | c.2117A>T p.Q706L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63391641; called by muse, mutect2, varscan2
- ERV3-1 | c.160G>C p.A54P | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV99275271; called by muse, mutect2, varscan2
- ESYT2 | c.1752G>T p.W584C (on ENST00000613624; = p.W508C on NM_020728.3) | Missense Mutation (SNP) | VAF 95/109 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51752831; called by muse, mutect2, varscan2
- ESYT3 | c.2052T>G p.S684R | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV67441359; called by muse, mutect2, varscan2
- ETV3L | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV71901141; called by muse, mutect2, varscan2
- EVI2A | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as COSV55986379; called by muse, mutect2, varscan2
- EXOSC9 | c.20C>G p.S7* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | catalogued as rs1385943891, COSV54666659; called by muse, mutect2
- EZHIP | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57955285, COSV57956590; called by muse, mutect2, varscan2
- FAM104A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); catalogued as rs377592119, COSV52148722; called by muse, mutect2, varscan2
- FAM114A1 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV62673482; called by muse, mutect2, varscan2
- FAM133A | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59076342; called by muse, mutect2, varscan2
- FAM135B | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52727357, COSV52735099; called by muse, mutect2, varscan2
- FAM135B | c.2020G>C p.G674R | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV52707397, COSV52735114; called by muse, mutect2, varscan2
- FAM149A | c.1316G>T p.G439V (on ENST00000356371 / NM_001367768.2; = p.G148V on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57028262; called by muse, mutect2, varscan2
- FAM168B | c.123G>T p.M41I | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66304286; called by muse, mutect2, varscan2
- FAM47A | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 125/141 reads (89%) | catalogued as COSV60497895; called by muse, mutect2, varscan2
- FAM47A | c.1795C>T p.L599F | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.808); catalogued as COSV60497906; called by muse, mutect2, varscan2
- FAM71C | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1435621050, COSV100175667; called by muse, mutect2
- FASN | c.6077G>A p.R2026H | Missense Mutation (SNP) | VAF 68/80 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs769327857, COSV60757023; called by muse, mutect2, varscan2
- FAT3 | c.5029C>A p.Q1677K | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.868); catalogued as rs748788205, COSV53133086; called by muse, mutect2, varscan2
- FAT3 | c.5399C>A p.A1800D | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53133111; called by muse, mutect2, varscan2
- FAT3 | c.12534G>T p.K4178N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV53133135; called by muse, mutect2, varscan2
- FBLN1 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV53049477; called by muse, mutect2, varscan2
- FBN2 | c.6406T>A p.W2136R | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52524170; called by muse, mutect2, varscan2
- FBN3 | c.7717G>T p.A2573S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.673); catalogued as COSV54464677; called by muse, mutect2, varscan2
- FEZF1 | c.1295C>A p.T432K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100484502, COSV58659100; called by muse, mutect2, varscan2
- FGFBP1 | c.609G>T p.M203I | Missense Mutation (SNP) | VAF 96/129 reads (74%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99468945; called by muse, mutect2, varscan2
- FGFBP1 | c.608T>A p.M203K | Missense Mutation (SNP) | VAF 97/130 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99468950; called by muse, mutect2, varscan2
- FGR | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64969600; called by muse, mutect2, varscan2
- FKBP7 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1339843145, COSV51846772; called by muse, mutect2, varscan2
- FLCN | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 31/39 reads (79%) | catalogued as COSV53260795; called by muse, mutect2, varscan2
- FLG2 | c.776G>C p.R259T | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as COSV66169854; called by muse, mutect2, varscan2
- FLT4 | c.2091G>T p.M697I | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as COSV56113113; called by muse, mutect2, varscan2
- FOLH1 | c.169A>T p.N57Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.261); catalogued as COSV57051502; called by muse, mutect2, varscan2
- FOXK1 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 181/419 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV61066882; called by muse, mutect2, varscan2
- FRAS1 | c.8569C>T p.R2857W | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs552527828, COSV53598349; called by muse, mutect2, varscan2
- FUT9 | c.636C>A p.S212R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV100133227; called by muse, mutect2, varscan2
- FYB2 | c.1278C>G p.H426Q | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV58586378; called by muse, mutect2, varscan2
- GATB | c.336C>G p.N112K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56131351; called by muse, mutect2, varscan2
- GC | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV56738125, COSV99909555; called by muse, mutect2, varscan2
- GCC2 | c.1850G>T p.C617F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.174); catalogued as COSV59177705; called by muse, mutect2, varscan2
- GCK | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60787215; called by muse, mutect2, varscan2
- GET3 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1349129346, COSV62002620; called by muse, mutect2, varscan2
- GFER | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV50191621; called by muse, mutect2, varscan2
- GIN1 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 140/205 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67537110; called by muse, mutect2, varscan2
- GINS2 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV53680618; called by muse, mutect2, varscan2
- GLI1 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV57364038; called by muse, mutect2
- GLI4 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV60682298, COSV60682678; called by muse, varscan2
- GLUL | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV59382603; called by muse, mutect2, varscan2
- GMPPA | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 91/316 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58007468; called by muse, mutect2, varscan2
- GNAI1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100650413; called by muse, mutect2, varscan2
- GP2 | c.1069C>T p.L357F (on ENST00000381362 / NM_001007240.3; = p.L354F on NM_001502.4) | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258841751, COSV56894935; called by muse, mutect2, varscan2
- GRID2 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs745533496, COSV56224414; called by muse, mutect2, varscan2
- GRM8 | c.2011A>T p.N671Y | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58840181; called by muse, mutect2, varscan2
- GSS | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as rs781666523, COSV53813413; called by muse, mutect2, varscan2
- GSTM2 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV53982888; called by muse, mutect2, varscan2
- GUCY2C | c.1718T>C p.L573S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53791814; called by muse, mutect2, varscan2
- H4C8 | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); catalogued as rs752058100, COSV99175463; called by muse, mutect2, varscan2
- HAPLN1 | c.494C>A p.P165Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776371363, COSV57149424; called by muse, mutect2, varscan2
- HAVCR1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV59401001; called by muse, mutect2, varscan2
- HCN1 | c.774G>C p.R258S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100302738, COSV57519790; called by muse, mutect2, varscan2
- HDAC8 | c.118A>G p.M40V | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65227863; called by muse, mutect2, varscan2
- HEATR1 | c.5575G>A p.E1859K | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV63981823; called by muse, mutect2, varscan2
- HEPACAM2 | c.440C>G p.T147R (on ENST00000394468 / NM_001039372.4; = p.T135R on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV59061471; called by muse, mutect2, varscan2
- HERC4 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV53272718; called by muse, mutect2, varscan2
- HERC6 | c.576C>A p.H192Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52031563, COSV99910478; called by muse, mutect2
- HERC6 | c.1580A>C p.Q527P | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52031587; called by muse, mutect2, varscan2
- HIP1R | c.1553A>G p.K518R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV53442646; called by muse, mutect2, varscan2
- HMX2 | c.680G>T p.S227I | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100378696; called by muse, mutect2, varscan2
- HNRNPR | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.22); catalogued as rs1334426484, COSV56422611; called by muse, mutect2, varscan2
- HOXB7 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs745772585, COSV99493909; called by muse, mutect2, varscan2
- HOXC10 | c.116T>C p.F39S | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV100329028; called by muse, mutect2, varscan2
- HOXD9 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99981786; called by muse, mutect2, varscan2
- HPCAL1 | c.137A>C p.D46A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.201); catalogued as COSV100323830; called by muse, mutect2, varscan2
- HPF1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV66422316; called by muse, varscan2
- HSPB7 | c.466C>G p.H156D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as COSV61308236; called by muse, mutect2, varscan2
- HTR1E | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1300719194, COSV59508856; called by muse, mutect2, varscan2
- IFNA4 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV101427023, COSV70180393; called by muse, mutect2, varscan2
- IFNA7 | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV53331616; called by muse, mutect2, varscan2
- IGSF1 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100811922; called by muse, mutect2, varscan2
- IGSF21 | c.838A>T p.S280C | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV52136979; called by muse, mutect2, varscan2
- IGSF6 | c.601C>A p.R201S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs192939219, COSV51678745, COSV51679591; called by muse, mutect2, varscan2
- IL18RAP | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV51827075; called by muse, mutect2, varscan2
- IL9R | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as COSV54900549; called by muse, mutect2, varscan2
- IRS4 | c.3014C>A p.T1005K | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV64534504; called by muse, mutect2, varscan2
- ISLR2 | c.585G>T p.W195C | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62302632; called by muse, mutect2, varscan2
- ITGAD | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771219273, COSV66758590; called by muse, mutect2, varscan2
- ITK | c.1799A>G p.E600G | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV70063359; called by muse, mutect2, varscan2
- ITPR2 | c.2867G>T p.G956V | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1159113121, COSV67271529; called by muse, mutect2, varscan2
- ITPRIP | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 81/109 reads (74%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99532443; called by muse, mutect2, varscan2
- JMJD1C | c.3400C>A p.Q1134K | Missense Mutation (SNP) | VAF 111/154 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0.225); catalogued as COSV59516312; called by muse, mutect2, varscan2
- JOSD2 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV65350298; called by muse, mutect2, varscan2
- KCNA4 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60253665; called by muse, varscan2
- KCNB2 | c.2289G>T p.Q763H | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs866260081, COSV73049092, COSV73051127; called by muse, mutect2, varscan2
- KIAA1328 | c.1514C>A p.T505N | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs751677814, COSV54457764; called by muse, mutect2, varscan2
- KIAA1522 | c.862C>T p.Q288* (on ENST00000373480 / NM_001198972.2; = p.Q347* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 61/136 reads (45%) | catalogued as COSV53865078, COSV53865603; called by muse, mutect2, varscan2
- KIAA1841 | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.487); catalogued as COSV54376149; called by muse, mutect2, varscan2
- KIAA1958 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 142/345 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV61725110; called by muse, mutect2, varscan2
- KIF25 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs199956268, COSV63026358; called by muse, mutect2, varscan2
- KIF4B | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV101469212, COSV101469373; called by muse, mutect2, varscan2
- KLHDC9 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs772226634, COSV63509992; called by muse, mutect2, varscan2
- KLHL1 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100917087; called by muse, mutect2, varscan2
- KLHL13 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV53249569; called by muse, mutect2, varscan2
- KLHL22 | c.1789C>G p.L597V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56732909; called by muse, mutect2, varscan2
- KLHL40 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV55135390; called by muse, mutect2, varscan2
- KMT2C | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.93); catalogued as COSV100068483, COSV51421061, COSV51457733; called by muse, mutect2
- KMT2C | c.905G>T p.C302F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100071094, COSV51457750; called by muse, mutect2
- KMT5B | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV58567500; called by muse, mutect2, varscan2
- KRI1 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as COSV57265091; called by muse, mutect2, varscan2
- KRT35 | c.419T>A p.M140K | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV55843668; called by muse, mutect2, varscan2
- KRT8 | c.369G>C p.W123C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV53177899; called by muse, mutect2, varscan2
- KRTAP13-3 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61879624; called by muse, mutect2, varscan2
- KRTAP6-3 | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | PolyPhen benign (0.173); catalogued as COSV66963082; called by muse, mutect2, varscan2
- L3MBTL2 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53434101; called by muse, mutect2, varscan2
- LAMA1 | c.3905A>T p.E1302V | Missense Mutation (SNP) | VAF 101/119 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs777615838, COSV67539436; called by muse, mutect2, varscan2
- LAMA1 | c.1817_1818insT p.H607Afs*3 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | catalogued as COSV101055433; called by mutect2, pindel, varscan2
- LAMA2 | c.4369G>A p.G1457R | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV70350890; called by muse, mutect2, varscan2
- LAMC1 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV51149933; called by muse, mutect2, varscan2
- LBP | c.1081T>A p.Y361N | Missense Mutation (SNP) | VAF 203/412 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54141319; called by muse, mutect2, varscan2
- LCT | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV51467434; called by muse, mutect2, varscan2
- LEFTY2 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs767003638, COSV64747218; called by muse, mutect2, varscan2
- LEXM | c.527A>T p.Y176F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs1465543918, COSV64023250; called by muse, mutect2, varscan2
- LHX8 | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 60/137 reads (44%) | catalogued as COSV53957785; called by muse, mutect2, varscan2
- LIG4 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 257/731 reads (35%) | catalogued as COSV63597385; called by muse, mutect2, varscan2
- LMAN2 | c.388G>T p.G130* | Nonsense Mutation (SNP) | VAF 154/367 reads (42%) | catalogued as COSV57425001; called by muse, mutect2, varscan2
- LMBR1L | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as rs943663626, COSV57267537, COSV57268239; called by muse, mutect2, varscan2
- LPP | c.719C>G p.S240* | Nonsense Mutation (SNP) | VAF 10/182 reads (5%) | catalogued as COSV57098899; called by muse, mutect2
- LRIT3 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59986076; called by muse, mutect2, varscan2
- LRP1B | c.6373G>T p.G2125C | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67241451; called by muse, mutect2, varscan2
- LRP4 | c.4046A>G p.D1349G | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs1400266967, COSV66136740; called by muse, mutect2, varscan2
- LRRC8E | c.209A>C p.Q70P | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV60718598; called by muse, mutect2, varscan2
- LRRIQ1 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV67833206; called by muse, mutect2, varscan2
- LSAMP | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61298839; called by muse, mutect2, varscan2
- LTBP2 | c.4849T>A p.W1617R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56210121; called by muse, mutect2, varscan2
- LY9 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.425); catalogued as COSV54435290; called by muse, varscan2
- MADD | c.3934A>C p.K1312Q | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60625915; called by muse, mutect2, varscan2
- MAP2K2 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as rs150369301; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- MAP2K6 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63006609; called by muse, mutect2, varscan2
- MAPKAP1 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as COSV56370111; called by muse, mutect2, varscan2
- MARCHF11 | c.938del p.R313Qfs*3 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | catalogued as COSV60131288; called by mutect2, pindel, varscan2
- MBTPS1 | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58571448; called by muse, mutect2, varscan2
- MCM5 | c.596+1G>A p.X199_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | catalogued as rs1365213097, COSV53346768; called by muse, mutect2, varscan2
- MDGA2 | c.2062G>T p.A688S (on ENST00000399232 / NM_001113498.2; = p.A390S on NM_182830.4) | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as COSV62099789; called by muse, mutect2, varscan2
- MDM2 | c.359-1G>T p.X120_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV50700350; called by muse, mutect2, varscan2
- MED12 | c.2437C>T p.Q813* | Nonsense Mutation (SNP) | VAF 120/155 reads (77%) | catalogued as COSV61344891; called by muse, mutect2, varscan2
- MED13 | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs368935603; called by muse, mutect2, varscan2
- MEGF10 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs756451956, COSV57252002; called by muse, mutect2, varscan2
- MICAL2 | c.5668A>G p.R1890G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56287013; called by mutect2, varscan2
- MMP1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV59510812; called by muse, mutect2, varscan2
- MMP25 | c.1431C>G p.F477L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100339361; called by muse, mutect2
- MMRN1 | c.3447C>A p.Y1149* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV53339104; called by muse, mutect2, varscan2
- MOGAT2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as rs146774065; called by muse, mutect2, varscan2
- MOV10L1 | c.1662G>T p.M554I | Missense Mutation (SNP) | VAF 67/85 reads (79%) | SIFT tolerated (0.27); PolyPhen benign (0.085); catalogued as COSV53174246; called by muse, mutect2, varscan2
- MPHOSPH6 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99259109; called by muse, mutect2, varscan2
- MS4A15 | c.646G>T p.D216Y (on ENST00000405633 / NM_001098835.2; = p.D123Y on NM_152717.3) | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100558847, COSV61961804; called by muse, varscan2
- MTF1 | c.354T>G p.I118M | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65961513; called by muse, mutect2, varscan2
- MTMR7 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 54/142 reads (38%) | catalogued as COSV51667786; called by muse, mutect2, varscan2
- MTSS1 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | catalogued as COSV61498090; called by muse, mutect2, varscan2
- MTUS2 | c.2395C>A p.P799T | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); catalogued as COSV70917798; called by muse, mutect2, varscan2
- MUC16 | c.20007C>G p.I6669M | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.295); catalogued as rs768444026, COSV67455052, COSV67476040; called by muse, mutect2, varscan2
- MUC3A | c.7171G>A p.G2391S | Missense Mutation (SNP) | VAF 172/402 reads (43%) | SIFT tolerated, low confidence (0.57); catalogued as rs769951239, COSV60218753; called by muse, mutect2, varscan2
- MYBL1 | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 9/258 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV72919058; called by muse, mutect2
- MYCBP2 | c.10546G>C p.E3516Q (on ENST00000357337; = p.E3554Q on NM_015057.5) | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.628); catalogued as COSV62026486; called by muse, mutect2, varscan2
- MYH6 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100676361; called by mutect2, varscan2
- MYLK3 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV67362581; called by muse, mutect2, varscan2
- MYO16 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 148/281 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.441); catalogued as COSV51802532; called by muse, mutect2, varscan2
- MYO16 | c.1409C>A p.P470H | Missense Mutation (SNP) | VAF 195/583 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51802552; called by muse, mutect2, varscan2
- MYT1L | c.1469C>A p.P490Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as COSV67710116; called by muse, mutect2, varscan2
- MYT1L | c.1468C>A p.P490T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.399); catalogued as COSV101219333, COSV67713550; called by muse, mutect2, varscan2
- NAALADL2 | c.1774G>C p.A592P | Missense Mutation (SNP) | VAF 120/387 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.478); catalogued as COSV71985444; called by muse, mutect2, varscan2
- NALCN | c.4835C>T p.P1612L | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV51945661, COSV99215309; called by muse, mutect2, varscan2
- NBAS | c.2920C>T p.Q974* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV55724569; called by muse, mutect2, varscan2
- NEBL | c.2965G>T p.D989Y | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs868003827, COSV65801682, COSV65804017; called by muse, mutect2, varscan2
- NEK11 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV63581949; called by muse, mutect2, varscan2
- NETO1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100198341; called by muse, mutect2, varscan2
- NFAT5 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV63029089; called by muse, varscan2
- NLGN1 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64338452; called by muse, mutect2, varscan2
- NLGN4X | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 68/78 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52024663; called by muse, mutect2, varscan2
- NLRP14 | c.3137A>T p.Q1046L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV55068790; called by muse, mutect2, varscan2
- NLRP3 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV60227106; called by muse, mutect2, varscan2
- NLRP3 | c.2391G>T p.K797N | Missense Mutation (SNP) | VAF 141/221 reads (64%) | SIFT tolerated (0.62); PolyPhen benign (0.044); catalogued as COSV60227124; called by muse, mutect2, varscan2
- NMNAT2 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV54269516; called by muse, mutect2
- NOVA1 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as rs752004813, COSV99946777; called by muse, varscan2
- NR1H4 | c.489A>T p.R163S (on ENST00000551379 / NM_001206993.2; = p.R153S on NM_005123.4) | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV51853616; called by muse, mutect2, varscan2
- NR3C1 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV99196121; called by muse, mutect2, varscan2
- NR4A1 | c.1335G>T p.E445D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV54484173; called by muse, mutect2, varscan2
- NRAP | c.4418T>C p.M1473T (on ENST00000359988 / NM_001322945.2; = p.M1438T on NM_006175.4) | Missense Mutation (SNP) | VAF 83/109 reads (76%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV63491897; called by muse, mutect2, varscan2
- NT5E | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV57629102; called by muse, mutect2, varscan2
- NTF3 | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV58417833; called by muse, mutect2, varscan2
- NUP205 | c.2840T>C p.L947P | Missense Mutation (SNP) | VAF 95/234 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53661448; called by muse, mutect2, varscan2
- OAS1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs771818638, COSV99177085; called by muse, mutect2, varscan2
- OBSCN | c.11130G>C p.R3710S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs1040581363, COSV52789835; called by muse, mutect2, varscan2
- ODF3L2 | c.103T>A p.C35S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV100205288; called by muse, mutect2, varscan2
- OPLAH | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs782205791, COSV70678466; called by muse, varscan2
- OPTC | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65868043; called by muse, mutect2, varscan2
- OPTN | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53811620; called by muse, mutect2, varscan2
- OR10A5 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 122/327 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55054769, COSV55056166; called by muse, mutect2, varscan2
- OR10AG1 | c.734C>A p.A245E | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV56633504; called by muse, mutect2, varscan2
- OR10S1 | c.763T>A p.C255S | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73342873; called by muse, mutect2, varscan2
- OR1Q1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV52918347; called by muse, mutect2, varscan2
- OR1Q1 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 115/293 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV52917180, COSV52918361; called by muse, mutect2, varscan2
- OR2C1 | c.168T>A p.H56Q | Missense Mutation (SNP) | VAF 130/313 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV100514875; called by muse, mutect2, varscan2
- OR2C3 | c.358T>G p.S120A | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63575414; called by muse, mutect2, varscan2
- OR2L13 | c.371C>A p.A124D | Missense Mutation (SNP) | VAF 160/293 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100813754, COSV63555581; called by muse, mutect2, varscan2
- OR2L2 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV63555577; called by muse, mutect2, varscan2
- OR2M3 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 246/435 reads (57%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs949127276, COSV71758924, COSV71759233; called by muse, mutect2, varscan2
- OR2M3 | c.842T>G p.L281R | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV71759120; called by muse, mutect2, varscan2
- OR2T6 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104418567, COSV63216612; called by muse, mutect2, varscan2
- OR4D2 | c.319T>G p.L107V | Missense Mutation (SNP) | VAF 145/252 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV73459798; called by muse, mutect2, varscan2
- OR4Q3 | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59179183; called by muse, mutect2, varscan2
- OR4X1 | c.252del p.F84Lfs*30 | Frame Shift Del (DEL) | VAF 43/121 reads (36%) | catalogued as COSV60722317; called by mutect2, pindel, varscan2
- OR51V1 | c.266G>T p.W89L | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as COSV58315550; called by muse, mutect2, varscan2
- OR52E4 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57625266; called by muse, mutect2, varscan2
- OR52N5 | c.26G>A p.W9* | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | catalogued as COSV57699089; called by muse, mutect2, varscan2
- OR5A2 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.839); catalogued as COSV57391351; called by muse, mutect2, varscan2
- OR5B21 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV64482043, COSV64482315; called by muse, mutect2, varscan2
- OR5K3 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV67350276; called by muse, mutect2, varscan2
- OR5K4 | c.169A>T p.T57S | Missense Mutation (SNP) | VAF 153/572 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV100721309; called by muse, mutect2, varscan2
- OR5L1 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV61734475; called by muse, mutect2, varscan2
- OR5M11 | c.533G>C p.C178S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV101602024; called by muse, mutect2, varscan2
- OR6C75 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58552611; called by muse, mutect2, varscan2
- ORM1 | c.172T>G p.S58A | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV52279878; called by muse, mutect2, varscan2
- OSBPL7 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50110564; called by muse, varscan2
- OSBPL7 | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50110603; called by muse, varscan2
- OTUD7B | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); catalogued as COSV64916719; called by muse, mutect2, varscan2
- OXR1 | c.2197G>T p.G733C (on ENST00000442977 / NM_001198532.1; = p.G705C on NM_018002.3) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99860858; called by muse, mutect2, varscan2
- P2RX3 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV54443386; called by muse, mutect2, varscan2
- PAPOLG | c.76A>T p.S26C | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53183757; called by muse, mutect2, varscan2
- PAPPA2 | c.1767C>A p.S589R | Missense Mutation (SNP) | VAF 85/165 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62780816; called by muse, mutect2, varscan2
- PAPPA2 | c.3938C>A p.T1313N | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as rs746966389, COSV100867676; called by muse, mutect2, varscan2
- PARP14 | c.2221A>G p.K741E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV71734977; called by muse, mutect2, varscan2
- PARP14 | c.4242A>T p.K1414N | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV71734979; called by muse, mutect2, varscan2
- PATJ | c.4357G>C p.G1453R | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57165511; called by muse, mutect2, varscan2
- PCDH11X | c.2763G>T p.W921C | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV53479345; called by muse, mutect2, varscan2
- PCDH11X | c.3701G>T p.S1234I | Missense Mutation (SNP) | VAF 164/190 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); catalogued as COSV100013400, COSV53479414; called by muse, varscan2
- PCDHA3 | c.2039C>G p.S680C | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1554122668, COSV100793067, COSV63543102; called by muse, mutect2, varscan2
- PCDHA9 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.249); catalogued as rs782164172, COSV65324257, COSV65328310; called by muse, mutect2, varscan2
- PCDHGA2 | c.1421T>C p.V474A | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); catalogued as COSV53975738; called by muse, mutect2, varscan2
- PCDHGA2 | c.2170C>G p.L724V | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV53975745; called by muse, mutect2, varscan2
- PCDHGA3 | c.273C>A p.D91E | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53975759; called by muse, mutect2, varscan2
- PCDHGB3 | c.365T>A p.L122Q | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as COSV53975778; called by muse, mutect2, varscan2
- PCK2 | c.470T>C p.M157T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV53749556; called by muse, mutect2, varscan2
- PCLO | c.13282G>T p.A4428S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV61645286; called by muse, mutect2, varscan2
- PCLO | c.9083G>T p.G3028V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61645294; called by muse, mutect2, varscan2
- PCNX3 | c.298del p.E100Sfs*21 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as COSV58420348; called by mutect2, pindel, varscan2
- PDCD10 | c.343A>T p.S115C | Missense Mutation (SNP) | VAF 155/364 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101208516; called by muse, mutect2, varscan2
- PDE1C | c.1390G>T p.G464* | Nonsense Mutation (SNP) | VAF 59/141 reads (42%) | catalogued as COSV58514457, COSV58518309; called by muse, mutect2, varscan2
- PDE6G | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 65/70 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs150256730; called by muse, mutect2, varscan2
- PDGFRA | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57266225, COSV57271287; called by muse, mutect2, varscan2
- PDGFRB | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV55806843; called by muse, mutect2, varscan2
- PDZD2 | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56858751; called by muse, mutect2, varscan2
- PEAR1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV52774064; called by muse, mutect2, varscan2
- PEG3 | c.4274C>G p.P1425R | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV55638133; called by muse, mutect2, varscan2
- PFKL | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.526); catalogued as rs756530116, COSV62464058; called by muse, mutect2, varscan2
- PHLDA1 | c.1091C>G p.S364W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.441); catalogued as rs1381373498, COSV56997691; called by muse, mutect2, varscan2
- PHOSPHO2 | c.7A>G p.I3V | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99775602; called by muse, mutect2, varscan2
- PICK1 | c.1012G>C p.V338L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.695); catalogued as COSV57635912, COSV57636197; called by muse, mutect2, varscan2
- PIGK | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV63062594; called by muse, mutect2, varscan2
- PIGL | c.385A>G p.R129G | Missense Mutation (SNP) | VAF 118/169 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV56686277; called by muse, mutect2, varscan2
- PIK3CB | c.403C>A p.H135N | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV100005323; called by muse, mutect2, varscan2
- PIK3CG | c.2918A>G p.K973R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV63249952; called by muse, mutect2, varscan2
- PKHD1 | c.10709C>T p.S3570L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.441); catalogued as CM051187, COSV100944528, COSV64393361; called by muse, mutect2, varscan2
- PLA2G4A | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66554947; called by muse, mutect2, varscan2
- PLAG1 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV57612777; called by muse, mutect2, varscan2
- PLB1 | c.4031C>T p.S1344F | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59829130; called by muse, mutect2, varscan2
- PLCB1 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62057721; called by muse, mutect2, varscan2
- PLCB4 | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV53806725; called by muse, mutect2, varscan2
- PLCG1 | c.1725G>T p.E575D | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54820276; called by muse, mutect2, varscan2
- PLOD2 | c.1685G>C p.C562S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51466234; called by muse, mutect2, varscan2
- PNLIP | c.460-1G>A p.X154_splice | Splice Site (SNP) | VAF 32/40 reads (80%) | catalogued as COSV65041014; called by muse, varscan2
- PNRC1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.344); catalogued as rs752226092, COSV100259820; called by muse, mutect2, varscan2
- POTEH | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV100624797; called by muse, mutect2, varscan2
- PPFIA2 | c.2014del p.E672Nfs*17 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as COSV99048590; called by pindel, varscan2
- PPFIA2 | c.1361G>C p.R454T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV61039471; called by muse, mutect2, varscan2
- PPIG | c.968G>C p.R323P | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53644097; called by muse, mutect2, varscan2
- PPP1R7 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.625); catalogued as COSV52145673; called by muse, mutect2, varscan2
- PRDM11 | c.1039C>G p.L347V (on ENST00000530656 / NM_001359633.1; = p.L313V on NM_001256695.1) | Missense Mutation (SNP) | VAF 119/277 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs776483937, COSV55441254; called by muse, mutect2, varscan2
- PRDM9 | c.882+1G>T p.X294_splice | Splice Site (SNP) | VAF 38/88 reads (43%) | catalogued as COSV57008561; called by muse, mutect2, varscan2
- PRELID2 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV58280671; called by muse, mutect2, varscan2
- PRKDC | c.9161A>C p.Q3054P | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.447); catalogued as rs1327058338, COSV58056501; called by muse, mutect2, varscan2
- PRPF8 | c.4725G>T p.Q1575H | Missense Mutation (SNP) | VAF 279/347 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59261669, COSV59264698; called by muse, mutect2, varscan2
- PRR11 | c.127A>T p.R43* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as COSV51877537; called by muse, mutect2, varscan2
- PRSS21 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV50051666; called by muse, mutect2, varscan2
- PSMB5 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.77); PolyPhen benign (0.027); catalogued as rs1354480343, COSV100557291; called by muse, mutect2, varscan2
- PTCHD4 | c.1824G>T p.L608F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as COSV59788915; called by muse, mutect2, varscan2
- PTGDR | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 102/236 reads (43%) | catalogued as rs1222242686, COSV60094297; called by muse, varscan2
- PTPRD | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV61958673; called by muse, mutect2, varscan2
- PTPRK | c.2907C>G p.F969L (on ENST00000368215 / NM_001291984.2; = p.F970L on NM_002844.4) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100950514; called by muse, mutect2, varscan2
- PTPRK | c.1239G>T p.L413F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.466); catalogued as COSV63901434; called by muse, mutect2, varscan2
- PTPRM | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 67/104 reads (64%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.683); catalogued as COSV59867316; called by muse, mutect2, varscan2
- PTPRO | c.2249A>G p.D750G | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.339); catalogued as COSV55514299; called by muse, mutect2, varscan2
- PTPRU | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 110/281 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748279144, COSV60521665; called by muse, mutect2, varscan2
- PURG | c.118C>G p.P40A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV53302505, COSV53304753; called by muse, mutect2, varscan2
- PXDNL | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs777981874, COSV62491545; called by muse, mutect2, varscan2
- PYDC2 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 113/208 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV101573351; called by muse, mutect2, varscan2
- PYHIN1 | c.120A>T p.K40N | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV63722986; called by muse, mutect2, varscan2
- QKI | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV51696691; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51934985, COSV99241081; called by muse, mutect2, varscan2
- RAB27B | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV50494205, COSV50495222; called by muse, mutect2, varscan2
- RAB8A | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs775041655, COSV56292040; called by muse, mutect2, varscan2
- RAD54B | c.1116A>T p.K372N | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.82); catalogued as COSV60252672; called by muse, mutect2, varscan2
- RAG1 | c.1122C>G p.H374Q | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as COSV55026185; called by muse, mutect2, varscan2
- RALGAPA1 | c.3066G>C p.E1022D | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51887902; called by muse, mutect2, varscan2
- RALGAPB | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs1227562441, COSV53436767; called by muse, mutect2, varscan2
- RARS1 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 129/337 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV51564452; called by muse, mutect2, varscan2
- RB1 | c.2091C>G p.D697E | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs3092903; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RBL2 | c.2708C>A p.T903K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV50880858; called by muse, mutect2, varscan2
- RBM19 | c.1413G>T p.R471S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55694183; called by muse, mutect2, varscan2
- RDH11 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV101191388, COSV101191549; called by muse, mutect2, varscan2
- REG3A | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59410149, COSV59410240; called by muse, mutect2, varscan2
- RELCH | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56887732; called by muse, mutect2
- RGS18 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs181836022, COSV66508769; called by muse, mutect2, varscan2
- RGS8 | c.531G>C p.R177S (on ENST00000367556 / NM_001369564.2; = p.R195S on NM_033345.3) | Missense Mutation (SNP) | VAF 179/300 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV51117473; called by muse, mutect2, varscan2
- RHCG | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV51516788; called by muse, mutect2, varscan2
- RIMBP2 | c.2148G>T p.K716N | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV55476695; called by muse, mutect2, varscan2
- RIN3 | c.2353G>T p.D785Y | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53645516; called by muse, mutect2, varscan2
- RNF43 | c.2017A>G p.T673A | Missense Mutation (SNP) | VAF 125/355 reads (35%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.057); catalogued as COSV68458881; called by muse, mutect2, varscan2
- ROBO3 | c.992G>T p.S331I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV67301307; called by muse, mutect2, varscan2
- RPTN | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 467/1217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60167832; called by muse, mutect2, varscan2
- RRP12 | c.2974C>G p.L992V | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV59669065; called by muse, mutect2, varscan2
- RTL1 | c.1751C>A p.S584Y | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV66017115; called by muse, mutect2, varscan2
- RTRAF | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.371); catalogued as COSV99356094; called by muse, mutect2, varscan2
- RUVBL2 | c.1276A>G p.I426V | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55485901; called by muse, mutect2, varscan2
- RYR2 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.76); catalogued as COSV63694231; called by muse, mutect2, varscan2
- RYR2 | c.14446C>A p.H4816N | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV63694235; called by muse, mutect2, varscan2
- SAXO2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV59754388; called by muse, mutect2, varscan2
- SAYSD1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as rs781157395, COSV57723234; called by muse, mutect2, varscan2
- SCGB2B2 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV101002817; called by muse, mutect2, varscan2
- SCN3A | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1162073915, COSV51814712; called by muse, mutect2, varscan2
- SCN7A | c.1045T>G p.L349V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV69272730; called by muse, mutect2, varscan2
- SEC16A | c.3361A>G p.S1121G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.607); catalogued as COSV51531892; called by muse, mutect2, varscan2
- SEC31B | c.2413G>T p.A805S | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV64844849; called by muse, mutect2, varscan2
- SEMA3G | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs371791154, COSV99202503; called by muse, mutect2, varscan2
- SEPTIN5 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63530782; called by muse, mutect2, varscan2
- SERPINB11 | c.838A>T p.R280* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101236167; called by muse, mutect2
- SERTAD2 | c.806C>G p.S269* | Nonsense Mutation (SNP) | VAF 13/118 reads (11%) | catalogued as COSV100512206, COSV57640628; called by muse, mutect2, varscan2
- SFTPA1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 105/190 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368889920; called by muse, mutect2, varscan2
- SHANK1 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53254422; called by muse, mutect2, varscan2
- SHD | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56666642, COSV56667572; called by muse, mutect2, varscan2
- SIX3 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99578118; called by muse, mutect2, varscan2
- SKAP1 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV100411456; called by muse, mutect2, varscan2
- SKAP1 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.916); catalogued as COSV100411459, COSV100411823, COSV61147226; called by muse, mutect2, varscan2
- SLC14A2 | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 105/261 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54910568, COSV54915243; called by muse, mutect2, varscan2
- SLC1A6 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs540964903, COSV55669653, COSV55671594; called by muse, mutect2
- SLC24A3 | c.1217A>T p.E406V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60123695; called by muse, mutect2, varscan2
- SLC26A6 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT tolerated (0.64); PolyPhen benign (0.124); catalogued as COSV56573082; called by muse, mutect2, varscan2
- SLC28A2 | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 74/113 reads (65%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV61664492; called by muse, mutect2, varscan2
- SLC29A1 | c.1059+1G>A p.X353_splice | Splice Site (SNP) | VAF 55/127 reads (43%) | catalogued as COSV57579185; called by muse, mutect2, varscan2
- SLC35F1 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64505181; called by muse, mutect2, varscan2
- SLC35F3 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV64024693, COSV64028864; called by muse, mutect2, varscan2
- SLC36A2 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58861851, COSV58863893; called by muse, mutect2, varscan2
- SLC4A1AP | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1269955438, COSV58135765; called by muse, mutect2, varscan2
- SLC5A1 | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 141/355 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56686589; called by muse, mutect2, varscan2
- SLC7A10 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as COSV53505046; called by muse, mutect2, varscan2
- SLC9A9 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57233481; called by muse, mutect2, varscan2
- SLIT3 | c.1611G>A p.L537= | Splice Region (SNP) | VAF 39/115 reads (34%) | catalogued as COSV60592735; called by muse, mutect2, varscan2
- SLITRK2 | c.2074G>T p.V692L | Missense Mutation (SNP) | VAF 91/101 reads (90%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV59426694; called by muse, mutect2, varscan2
- SMYD3 | c.1186-2A>T p.X396_splice (on ENST00000490107 / NM_001375962.1; = p.X337_splice on NM_022743.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100830676; called by muse, mutect2, varscan2
- SNX14 | c.2519A>T p.Q840L (on ENST00000314673 / NM_001350535.1; = p.Q787L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as COSV59013772; called by muse, mutect2, varscan2
- SORCS1 | c.2088G>T p.R696S | Missense Mutation (SNP) | VAF 56/83 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV53878801; called by muse, mutect2, varscan2
- SPARC | c.821A>C p.D274A | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50559052; called by muse, mutect2, varscan2
- SPATA16 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 80/720 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.56); catalogued as COSV63530676; called by muse, varscan2
- SPATA31D1 | c.1821T>A p.H607Q | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV61197747; called by muse, mutect2, varscan2
- SPIDR | c.2610C>G p.Y870* | Nonsense Mutation (SNP) | VAF 120/283 reads (42%) | catalogued as rs201378745, COSV52381181; called by muse, mutect2, varscan2
- SPTLC3 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV100982964; called by muse, mutect2, varscan2
- SRD5A2 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51872187; called by muse, mutect2, varscan2
- SRRM2 | c.4502C>T p.S1501L | Missense Mutation (SNP) | VAF 145/346 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV57075866, COSV57078581; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.163C>G p.H55D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | PolyPhen benign (0.158); catalogued as COSV100231350; called by muse, mutect2, varscan2
- STAG3 | c.2909C>A p.P970H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs763206398, COSV57931999; called by muse, mutect2, varscan2
- STAT3 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV52889317; called by muse, mutect2, varscan2
- STRA8 | c.133C>T p.Q45* (on ENST00000275764; = p.Q23* on NM_182489.2) | Nonsense Mutation (SNP) | VAF 45/132 reads (34%) | catalogued as COSV51962076; called by muse, mutect2, varscan2
- STX16 | c.250G>A p.E84K (on ENST00000371141 / NM_001001433.3; = p.E63K on NM_003763.6) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV56606830; called by muse, mutect2
- SUN1 | c.2078G>A p.R693H (on ENST00000405266 / NM_001367651.1; = p.R573H on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769143587, COSV67450392; called by muse, mutect2, varscan2
- SUPT5H | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63240607; called by muse, mutect2, varscan2
- SYK | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 114/318 reads (36%) | catalogued as COSV101002386, COSV65328191; called by muse, varscan2
- SYNE1 | c.5875G>T p.V1959L (on ENST00000367255 / NM_182961.4; = p.V1966L on NM_033071.3) | Missense Mutation (SNP) | VAF 121/300 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55022029; called by muse, mutect2, varscan2
- TAS2R16 | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.066); catalogued as COSV50797094, COSV50797584; called by muse, mutect2, varscan2
- TAS2R50 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101114352; called by muse, mutect2
- TASOR | c.2401A>T p.T801S (on ENST00000355628 / NM_001365636.2; = p.T405S on NM_015224.3) | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100843397; called by muse, mutect2, varscan2
- TBC1D15 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59850423; called by muse, mutect2, varscan2
- TBC1D31 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54867733; called by muse, mutect2, varscan2
- TCEA3 | c.837A>T p.E279D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV71532017; called by muse, mutect2, varscan2
- TCHHL1 | c.2353G>T p.D785Y | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as rs775083392, COSV100916635, COSV64286322; called by muse, mutect2, varscan2
- TDO2 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs759094500, COSV72483911, COSV72483933; called by muse, mutect2, varscan2
- TDO2 | c.1197C>A p.Y399* | Nonsense Mutation (SNP) | VAF 34/66 reads (52%) | catalogued as COSV70809347; called by muse, mutect2, varscan2
- TDP1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV59644199; called by muse, mutect2, varscan2
- TECPR2 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV63971645; called by muse, mutect2, varscan2
- TENM2 | c.2305G>T p.V769L (on ENST00000518659 / NM_001122679.2; = p.V537L on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs368507082, COSV69134332; called by muse, mutect2
- TENM3 | c.2366G>T p.G789V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV69312329; called by muse, mutect2, varscan2
- TEX15 | c.454C>A p.Q152K (on ENST00000256246; = p.Q535K on NM_001350162.2) | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV56348558; called by muse, mutect2, varscan2
- THRAP3 | c.518A>T p.K173M | Missense Mutation (SNP) | VAF 209/536 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV63568593; called by muse, mutect2, varscan2
- THSD7A | c.3176C>T p.S1059F | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV70265040; called by muse, mutect2, varscan2
- THSD7A | c.2441G>T p.C814F | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70260683, COSV70267265; called by muse, mutect2, varscan2
- THSD7B | c.1889G>T p.R630I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55671705; called by muse, mutect2
- TIFAB | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV72345850; called by muse, mutect2, varscan2
- TJP1 | c.3897A>C p.K1299N | Missense Mutation (SNP) | VAF 168/210 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV62043302; called by muse, mutect2, varscan2
- TMC1 | c.631A>G p.M211V | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV52778505; called by muse, mutect2, varscan2
- TMC1 | c.1657T>C p.C553R | Missense Mutation (SNP) | VAF 159/386 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV52778517; called by muse, mutect2, varscan2
- TMEM132B | c.2087A>T p.Q696L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs771365891, COSV54758376; called by muse, mutect2, varscan2
- TMEM155 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs752331502, COSV100530049; called by mutect2, varscan2
- TMEM71 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV63458059; called by muse, mutect2, varscan2
- TMPO | c.1482C>G p.F494L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99701919; called by muse, mutect2, varscan2
- TMPRSS11A | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); catalogued as COSV58359405; called by muse, mutect2, varscan2
- TNIK | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV52686570; called by muse, mutect2
- TNNI2 | c.182T>A p.V61E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV53290158; called by muse, mutect2, varscan2
- TNR | c.2494A>T p.M832L | Missense Mutation (SNP) | VAF 83/126 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV54895556; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62626450, COSV62627275; called by muse, mutect2, varscan2
- TP53 | c.744del p.R249Gfs*96 | Frame Shift Del (DEL) | VAF 30/60 reads (50%) | catalogued as COSV52782654, COSV53050697, COSV53372256; called by mutect2, pindel, varscan2
- TP63 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 46/458 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV53210897; called by muse, mutect2, varscan2
- TPR | c.4459G>T p.E1487* | Nonsense Mutation (SNP) | VAF 64/120 reads (53%) | catalogued as COSV100823660, COSV66602511; called by muse, mutect2, varscan2
- TRAF3IP3 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs761562468, COSV50554621; called by muse, mutect2, varscan2
- TREH | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as rs782812969; called by muse, mutect2
- TRIM49 | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 34/148 reads (23%) | catalogued as COSV100315930; called by muse, mutect2, varscan2
- TRPA1 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV51565641; called by muse, mutect2, varscan2
- TRPM8 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.976); catalogued as COSV61222617; called by muse, mutect2, varscan2
- TSG101 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52650897; called by muse, mutect2, varscan2
- TTC21B | c.2951-2A>T p.X984_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54632077; called by muse, mutect2, varscan2
- TTC22 | c.657G>T p.E219D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100988158, COSV64881634; called by muse, mutect2, varscan2
- TTC27 | c.985G>C p.A329P | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV58653975; called by muse, mutect2, varscan2
- TTLL2 | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV53444588; called by muse, mutect2, varscan2
- TTLL4 | c.467G>C p.S156T | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV51437281; called by muse, mutect2, varscan2
- TTN | c.82859C>A p.P27620Q (on ENST00000591111; = p.P20196Q on NM_003319.4) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | PolyPhen probably damaging (0.999); catalogued as COSV100599640; called by muse, mutect2, varscan2
- TTN | c.82858C>A p.P27620T (on ENST00000591111; = p.P20196T on NM_003319.4) | Missense Mutation (SNP) | VAF 41/100 reads (41%) | PolyPhen probably damaging (0.999); catalogued as COSV60274171; called by muse, mutect2, varscan2
- TTN | c.55265C>G p.T18422R (on ENST00000591111; = p.T10998R on NM_003319.4) | Missense Mutation (SNP) | VAF 114/324 reads (35%) | PolyPhen probably damaging (0.998); catalogued as rs1560220, COSV60157836; called by muse, mutect2, varscan2
- TTN | c.23710A>G p.M7904V (on ENST00000591111; = p.M6977V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | PolyPhen benign (0); catalogued as COSV60157869; called by muse, mutect2, varscan2
- TTN | c.12515C>A p.T4172K (on ENST00000591111; = p.T4126K on NM_003319.4) | Missense Mutation (SNP) | VAF 130/321 reads (40%) | catalogued as COSV60157911; called by muse, mutect2, varscan2
- TTN | c.6069G>T p.K2023N (on ENST00000591111; = p.K1977N on NM_003319.4) | Missense Mutation (SNP) | VAF 91/209 reads (44%) | PolyPhen probably damaging (0.943); catalogued as COSV100625428, COSV60157958; called by muse, mutect2, varscan2
- TUBB4A | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV51157936; called by muse, mutect2, varscan2
- TUSC3 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV65877700, COSV65883577; called by muse, mutect2, varscan2
- UBA6 | c.1864A>G p.I622V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); catalogued as rs1272638875, COSV59178713; called by muse, mutect2, varscan2
- UBASH3A | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.159); catalogued as COSV52313768; called by muse, mutect2, varscan2
- UBE4A | c.721+3G>T | Splice Region (SNP) | VAF 72/146 reads (49%) | catalogued as COSV99347956; called by muse, mutect2, varscan2
- UBXN2B | c.808A>T p.I270L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV68309294; called by muse, mutect2, varscan2
- UGT2B17 | c.1053T>A p.N351K | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100497179; called by muse, mutect2, varscan2
- UMOD | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV56776924; called by muse, mutect2, varscan2
- UNC80 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 75/167 reads (45%) | catalogued as COSV55896474; called by muse, mutect2, varscan2
- UPK1B | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); catalogued as COSV51767731; called by muse, mutect2, varscan2
- URI1 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as rs771507685, COSV56351080; called by muse, mutect2, varscan2
- USH2A | c.7655C>A p.T2552N | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV100230895; called by muse, mutect2, varscan2
- USP7 | c.3063G>T p.M1021I | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV61215639; called by muse, mutect2, varscan2
- VAC14 | c.317A>T p.D106V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55755030; called by muse, varscan2
- VPS13C | c.7858G>A p.E2620K (on ENST00000644861 / NM_020821.3; = p.E2577K on NM_017684.5) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.24); catalogued as COSV51120968; called by muse, mutect2, varscan2
- VPS41 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV59650226; called by muse, mutect2, varscan2
- VPS8 | c.3817G>A p.D1273N (on ENST00000625842 / NM_001349294.1; = p.D1271N on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.711); catalogued as rs1336889194, COSV54989403; called by muse, mutect2
- WAC | c.1661C>G p.S554* | Nonsense Mutation (SNP) | VAF 63/142 reads (44%) | catalogued as COSV61568161; called by muse, mutect2, varscan2
- WDFY3 | c.4288G>T p.A1430S | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as COSV55705461; called by muse, mutect2, varscan2
- WDR17 | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472632961, COSV54576607, COSV99707036; called by mutect2, varscan2
- WDR35 | c.3490G>T p.A1164S (on ENST00000345530 / NM_001006657.2; = p.A1153S on NM_020779.4) | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV55604304; called by muse, mutect2, varscan2
- WSCD2 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV54577201, COSV54585482; called by muse, mutect2, varscan2
- WWP2 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63125823; called by muse, mutect2, varscan2
- YEATS2 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 262/499 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59367812; called by muse, mutect2, varscan2
- YLPM1 | c.6239A>G p.Y2080C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57821625; called by muse, mutect2, varscan2
- ZBED9 | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV71729534; called by muse, mutect2, varscan2
- ZDBF2 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV65627536; called by muse, mutect2, varscan2
- ZDHHC19 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs775811813, COSV56349211; called by muse, mutect2, varscan2
- ZDHHC22 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.341); catalogued as COSV100083692; called by muse, mutect2, varscan2
- ZFHX4 | c.8368G>A p.E2790K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV51455498; called by muse, mutect2, varscan2
- ZNF112 | c.277G>T p.V93L (on ENST00000337401 / NM_001083335.2; = p.V87L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100495550; called by muse, mutect2, varscan2
- ZNF202 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as rs1421836189, COSV60247558; called by muse, mutect2, varscan2
- ZNF215 | c.911G>T p.S304I | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as COSV53493713; called by muse, mutect2, varscan2
- ZNF236 | c.4417G>T p.D1473Y | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53491142; called by muse, mutect2, varscan2
- ZNF257 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV71309728; called by muse, mutect2, varscan2
- ZNF268 | c.919A>T p.N307Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV57213408; called by muse, mutect2, varscan2
- ZNF274 | c.334G>A p.E112K (on ENST00000610905; = p.E7K on NM_016324.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV58765200; called by muse, mutect2, varscan2
- ZNF343 | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1285788238, COSV53853768; called by muse, mutect2, varscan2
- ZNF521 | c.2971del p.R991Gfs*14 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | catalogued as COSV100831345; called by mutect2, pindel, varscan2
- ZNF536 | c.216G>C p.M72I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100834652, COSV62827356; called by muse, mutect2, varscan2
- ZNF536 | c.1453A>T p.K485* | Nonsense Mutation (SNP) | VAF 48/118 reads (41%) | catalogued as COSV62827366; called by muse, mutect2, varscan2
- ZNF623 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.233); catalogued as COSV71697251; called by muse, mutect2
- ZNF669 | c.1279T>A p.Y427N | Missense Mutation (SNP) | VAF 99/457 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260351364, COSV58538135; called by muse, mutect2, varscan2
- ZNF689 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as rs774978582, COSV54908383; called by muse, mutect2, varscan2
- ZNF71 | c.1207G>T p.V403L | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs199703109, COSV60148709; called by muse, mutect2, varscan2
- ZNF714 | c.1513G>T p.G505C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52513139; called by muse, mutect2, varscan2
- ZNF75D | c.660G>T p.W220C | Missense Mutation (SNP) | VAF 59/68 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV66132978; called by muse, mutect2, varscan2
- ZNF761 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV61888701; called by muse, mutect2, varscan2
- ZNF804A | c.441C>A p.N147K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1479722289, COSV56437430; called by muse, mutect2, varscan2
- ZRANB3 | c.3055G>T p.V1019L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1419766977, COSV99922890; called by mutect2, varscan2
- ZSCAN25 | c.668C>A p.T223N | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV53553555; called by muse, mutect2, varscan2
- ZWINT | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as COSV59185907; called by muse, mutect2, varscan2
- ADGRL3 | c.2890_2917del p.I964Sfs*18 (on ENST00000506720 / NM_001322402.2; = p.I896Sfs*18 on NM_015236.6) | Frame Shift Del (DEL) | VAF 48/227 reads (21%) | called by mutect2, pindel
- ALG13 | c.632_634del p.Y211del | In Frame Del (DEL) | VAF 20/95 reads (21%) | called by pindel, varscan2
- ANO6 | c.1796del p.G599Afs*6 | Frame Shift Del (DEL) | VAF 39/105 reads (37%) | called by mutect2, pindel, varscan2
- C3P1 | n.3313+2T>A | Splice Site (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- CARD14 | c.1875del p.L626Cfs*29 | Frame Shift Del (DEL) | VAF 58/98 reads (59%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.1619A>G p.K540R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FAM71A | c.511_532del p.I171Wfs*15 | Frame Shift Del (DEL) | VAF 116/326 reads (36%) | called by mutect2, pindel, varscan2
- GRAMD1B | c.1635G>C p.E545D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2
- HLA-B | c.546del p.Y183Tfs*31 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, varscan2
- IGHV3-30 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ITPR2 | c.4732dup p.W1578Lfs*12 | Frame Shift Ins (INS) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- KCNAB3 | c.380_382delinsTTT p.T127_A128delinsIS | Missense Mutation (TNP) | VAF 7/71 reads (10%) | called by muse*, pindel, varscan2*
- LARP4B | c.2122_2130del p.D708_R710del | In Frame Del (DEL) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- MYB | c.1591del p.E531Nfs*21 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- OR6Y1 | c.724del p.A242Hfs*9 | Frame Shift Del (DEL) | VAF 31/151 reads (21%) | called by mutect2, pindel, varscan2
- PCDHB15 | c.1857_1858del p.H620Qfs*140 | Frame Shift Del (DEL) | VAF 32/131 reads (24%) | called by pindel, varscan2
- PLEC | c.12439_12440del p.A4147Rfs*46 (on ENST00000322810 / NM_201380.4; = p.A4037Rfs*46 on NM_000445.5) | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by pindel, varscan2
- PTPN20 | c.581C>G p.P194R | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.5062del p.S1688Afs*100 | Frame Shift Del (DEL) | VAF 39/135 reads (29%) | called by mutect2, pindel, varscan2
- SLC35F1 | c.847+1del | Frame Shift Del (DEL) | VAF 74/242 reads (31%) | called by mutect2, pindel, varscan2
- SPANXN2 | c.176_177delinsT p.K59Ifs*5 | Frame Shift Del (DEL) | VAF 62/191 reads (32%) | called by pindel, varscan2*
- TMEM151A | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.743); called by muse, mutect2
- TRAPPC6A | c.316dup p.M106Nfs*32 (on ENST00000585934 / NM_001270891.2; = p.M120Nfs*32 on NM_024108.3) | Frame Shift Ins (INS) | VAF 15/19 reads (79%) | called by mutect2, varscan2
- TRAPPC6A | c.314dup p.M106Dfs*32 (on ENST00000585934 / NM_001270891.2; = p.M120Dfs*32 on NM_024108.3) | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | called by mutect2*, pindel, varscan2*
- TTN | c.25958_25974delinsT p.R8653Ifs*2 (on ENST00000591111; = p.R7726Ifs*2 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by pindel, varscan2*
- ZNF488 | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZP4 | c.1525del p.V509Wfs*8 | Frame Shift Del (DEL) | VAF 43/190 reads (23%) | called by mutect2, pindel, varscan2
- ABCA3 | c.3969C>T p.L1323= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV57055796; called by muse, mutect2, varscan2
- ABCA8 | c.781C>A p.R261= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as COSV52204923; called by muse, mutect2, varscan2
- ABCC1 | c.747G>A p.T249= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs1209386105, COSV60688625; called by muse, mutect2, varscan2
- ADAMTS12 | c.3171C>A p.S1057= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV61267433; called by muse, mutect2, varscan2
- ADGRB3 | c.3075T>C p.F1025= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV53250578; called by muse, mutect2, varscan2
- AFTPH | c.2025G>A p.L675= | Silent (SNP) | VAF 79/193 reads (41%) | catalogued as COSV53219289; called by muse, mutect2, varscan2
- ALDH9A1 | c.168C>T p.F56= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV61340246; called by muse, mutect2, varscan2
- ALMS1 | c.5391G>T p.G1797= | Silent (SNP) | VAF 101/236 reads (43%) | catalogued as COSV52513432; called by muse, mutect2, varscan2
- ANKRD33 | c.204G>C p.A68= (on ENST00000340970 / NM_001304459.2; = p.A203= on NM_182608.4) | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV56606119, COSV56607096; called by muse, mutect2, varscan2
- ANO6 | c.795G>T p.R265= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV57663372; called by muse, mutect2, varscan2
- AP3B1 | c.2478A>T p.P826= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV54886781; called by muse, mutect2, varscan2
- ARHGAP18 | c.651G>T p.L217= | Silent (SNP) | VAF 71/146 reads (49%) | catalogued as COSV63765012; called by muse, mutect2, varscan2
- ARHGAP31 | c.2610C>T p.I870= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as rs1475004656, COSV51789586; called by muse, mutect2, varscan2
- BBS10 | c.1791T>A p.G597= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as COSV67913280; called by muse, mutect2, varscan2
- BIRC7 | c.468G>T p.R156= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as COSV53901793; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1407C>T p.F469= | Silent (SNP) | VAF 77/504 reads (15%) | catalogued as COSV57279718; called by muse, mutect2, varscan2
- C12orf43 | c.576G>A p.K192= | Silent (SNP) | VAF 71/171 reads (42%) | catalogued as rs200226647, COSV99982250; called by muse, mutect2, varscan2
- C9 | c.1491C>T p.A497= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV54678180; called by muse, mutect2, varscan2
- CA7 | c.48G>T p.S16= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs781369944, COSV100623731; called by muse, mutect2, varscan2
- CBL | c.597A>T p.I199= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV50643985; called by muse, mutect2, varscan2
- CBLL1 | c.795A>G p.A265= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV56029586; called by muse, mutect2, varscan2
- CD44 | c.534G>A p.V178= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs761769817, COSV53530033; called by muse, mutect2, varscan2
- CDH10 | c.861C>A p.A287= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV52586168; called by muse, mutect2, varscan2
- CDH11 | c.336C>A p.A112= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs1406665739, COSV51767384; called by muse, mutect2, varscan2
- CENPF | c.5859C>T p.L1953= | Silent (SNP) | VAF 29/193 reads (15%) | catalogued as COSV65276162, COSV65279812; called by muse, mutect2
- CFAP54 | c.6270G>T p.L2090= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV61572984; called by muse, mutect2, varscan2
- CFAP91 | c.2109C>T p.I703= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV56342172; called by muse, mutect2, varscan2
- CHD1L | c.2121G>A p.L707= | Silent (SNP) | VAF 65/176 reads (37%) | catalogued as rs782440177, COSV100787370; called by muse, mutect2, varscan2
- CHRM5 | c.1305C>G p.V435= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV67247798; called by muse, mutect2, varscan2
- CILK1 | c.1728G>A p.Q576= (on ENST00000350082 / NM_001375397.1; = p.Q569= on NM_014920.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as COSV63154896; called by muse, varscan2
- CLTCL1 | c.4698C>T p.F1566= (on ENST00000427926 / NM_007098.4; = p.F1509= on NM_001835.4) | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs560109073, COSV53206078; called by muse, mutect2, varscan2
- COL4A3 | c.4704T>C p.P1568= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV67416696; called by muse, mutect2, varscan2
- CROCC | c.1650C>A p.G550= | Silent (SNP) | VAF 47/192 reads (24%) | catalogued as COSV65012374; called by muse, mutect2, varscan2
- CRYBG3 | c.6357G>A p.Q2119= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV51713338; called by muse, mutect2
- CSGALNACT2 | c.183A>T p.L61= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV65675952; called by muse, mutect2, varscan2
- CSMD2 | c.7209C>T p.L2403= | Silent (SNP) | VAF 76/216 reads (35%) | catalogued as COSV53897525; called by muse, mutect2, varscan2
- CWH43 | c.627C>A p.T209= | Silent (SNP) | VAF 57/74 reads (77%) | catalogued as COSV56940380; called by mutect2, varscan2
- DACT1 | c.1497G>A p.E499= | Silent (SNP) | VAF 77/197 reads (39%) | catalogued as rs145184753, COSV60021305, COSV60021753; called by muse, mutect2, varscan2
- DCAF4L2 | c.432G>C p.L144= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV60479877; called by muse, mutect2, varscan2
- DCAF5 | c.1071C>T p.I357= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as rs756857703, COSV58461234; called by muse, mutect2, varscan2
- DDX18 | c.939G>T p.L313= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as COSV99604401; called by muse, mutect2, varscan2
- DEPDC5 | c.3288A>G p.E1096= (on ENST00000400246; = p.E1165= on NM_014662.5) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV56702005; called by muse, mutect2
- DMRT3 | c.621C>T p.V207= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as COSV51905885; called by muse, mutect2, varscan2
- DNAH10 | c.8001T>C p.Y2667= (on ENST00000409039; = p.Y2606= on NM_207437.3) | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV68996196; called by muse, mutect2, varscan2
159 further variants in this file (0 protein-altering or splice-affecting, 134 silent, 25 other) are not listed here.
